Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2N1, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2N1-01A (Primary Tumor).

RNA Discrepancy		☒
Discrepancy/Discrepancy Primary Tumor		☒

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

TOTAL THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

Left lobe

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

pw
8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

3.0 cm greatest dimension

FOCALITY:

Multifocal

LYMPH NODES:

Metastatic carcinoma in 6 of 7 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2 cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Involved by invasive carcinoma
(deep margin)

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Lymphocytic Thyroiditis

NOTE: Parathyroid tissue found in right mid lobe.

Source: NCI Genomic Data Commons file a160b3fb-55dc-42f3-8d18-a10d5c101640 (TCGA-ET-A2N1.CD534E46-2105-4BC5-AE72-3BA55CE1394D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).